Surgical pathology report (de-identified scan), TCGA case TCGA-KK-A6E0, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-KK-A6E0-01A (Primary Tumor).

[page 1 of 3]
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) PROSTATE AND SEMINAL VESICLES:
Supplemental report to follow.
(B) BILATERAL PELVIC LYMPH NODES:
Nine lymph nodes, no tumor present. (0/9)

Entire report and diagnosis completed by

ICD-O 3
Adenocarcinoma NOS 8140/3
Adenocarcinoma, acinar 8140/3
Site Prostate NOS C61.9
JW 5/21/13

GROSS DESCRIPTION

- (A) PROSTATE AND SEMINAL VESICLES – Supplemental report to follow.
(B) BILATERAL PELVIC LYMPH NODES – A portion of fibroadipose tissue (5 x 4 x 0.7 cm) which is dissected to reveal 10 possible lymph nodes, ranging from 0.2 to 1 cm in greatest dimension.
SECTION CODE: B1, five possible lymph nodes; B2, B3, each contain two possible lymph nodes; B4, one lymph node, trisected.

CLINICAL HISTORY

None given.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Entire report and diagnosis completed by:

These tests have not been

Start of ADDENDUM

[page 2 of 3]
Specimen Date/Time:

ADDENDUM

This modified report is being issued to provide additional information/results.

Addendum completed by

DIAGNOSIS

- (A) PROSTATE AND SEMINAL VESICLES:
PROSTATIC ADENOCARCINOMA, GLEASON SCORE 9 (4 + 5). (SEE COMMENT)
TUMOR EXTENDING FOCALLY INTO EXTRAPROSTATIC TISSUE.
Margins of resection, free of tumor.
Right and left seminal vesicles, no tumor present.
Segments of right and left vasa deferentia, no tumor present.
PERINEURAL INVASION, PRESENT.
No lymphovascular invasion identified.
PROSTATIC INTRAEPITHELIAL NEOPLASIA (PIN), HIGH GRADE.

COMMENT

The prostate gland contains two foci of prostatic adenocarcinoma. Both tumor foci are located in the peripheral zone. The dominant tumor focus is located in the right anterolateral, right lateral, right posterolateral and right posterior peripheral zone. This tumor focus measures 2.0 x 1.0 cm in the largest cross-sectional dimension and it is present in two cross sections and extensively in the apex and base region. In the right superior neurovascular bundle region, this tumor focus extends into extraprostatic tissue. The extent of margin of extraprostatic extension is 4.0 mm. The margin of resection is free of tumor.

The second tumor focus is located in the left posterolateral peripheral zone, exclusively in the apical region. This tumor focus measures 1.0 x 0.2 cm in the largest cross-sectional dimension and it is present in a single apical section. This tumor is confined to the prostate. All margins of resection are free of tumor.

GROSS DESCRIPTION

- (A) PROSTATE AND SEMINAL VESICLES – A specimen consisting of a prostate, attached right and left seminal vesicles and attached segments of right and left vasa deferentia.

The prostate gland (4.7 x 2.7 x 3.0 cm, 28 grams, post fixation) has the usual shape. The soft tissue present along the left posterolateral aspect of the prostate appears slightly more abundant than along the right side. An area of firmness is noted on the right side of the prostate. Serial cross sections after fixation demonstrate an area consistent with tumor in the right side of the two cross sections of the prostate.

The seminal vesicles and segments of vasa deferentia are grossly free of tumor.

Also included in the container are three fragments of tubular structures consistent with vas deferens measuring 2.6 x 0.4 x 0.2 cm, 3.7 x 0.3 x 0.2 cm, 1.2 x 0.4 x 0.2 cm and a fragment of adipose tissue measuring 1.2 x 0.4 x 0.2 cm.

SECTION CODE: A1-A4, detached fragments of tissue; A5-A7, right seminal vesicle and segment of right vas deferens from the base towards the tip; A8-A10, left seminal vesicle and segment of left vas deferens from the base towards the tip; A11,

[page 3 of 3]
Specimen Date/Time:

prostatic base, right border; A12, A13, prostatic base, right posterior border; A14-A18, prostatic base, central portion; A19, prostatic base, left border; A20, A21, prostatic base, left posterior border; A22, A23, apex anterior; A24, A25, apex left; A26, A27, apex posterior; A28, A29, apex right; A30-A37, sections of the two cross sections of the prostate according to specimen radiograph.

The anterior aspect of the prostate is inked in green, left surface in red, right surface in yellow and posterior surface in black. Blue ink (A29) and orange ink (A34 and A35) denote surfaces that do not represent the true margin of resection.

SNOMED CODES

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file ff17bc2d-b32b-4425-9e09-3ca6d9ab6353 (TCGA-KK-A6E0.41BD5E57-29AE-41C8-96D7-2832C726E83B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).